MMRF case MMRF_2611 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a7e19b05-b3a7-4fac-a483-0f20bd8d4382

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,430 days); ISS stage: II; Days to last known disease status: 631 days (1.7 years); Days to last follow up: 631 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 136 days; Days to treatment end: 136 days.
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 358 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 379 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 57.4 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.304 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.38 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 4.95 mmol/L.
- Day 92 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 0.281 g/L; Immunoglobulin M 0.314 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.57 mmol/L.
- Day 169 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 4.27 g/L; Immunoglobulin A 0.387 g/L; Immunoglobulin M 0.216 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.66 mmol/L.
- Day 247 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 4.68 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.13 mmol/L.
- Day 358 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 3.02 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 5.06 mmol/L.
- Day 435 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.07 mmol/L.
- Day 522 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 5.9 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 631 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -7: Weight: 78 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2611_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2611_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
